Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6322, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6322-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. LEFT COLON

SPECIMEN(S):

A. LEFT COLON

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

A-left colon: Tumor mass is 9 cm away from the distal margin, called by

GROSS DESCRIPTION:

A. LEFT COLON

Received fresh labeled with the patient's identification and "left colon" is a 24 cm segment of colon with circumference of 7.5 cm with a suture designating the distal margin. The serosa is unremarkable. The mesocolon and serosa, subjacent to the mass, is inked black. A 9 x 6.5 x 3cm circumferential, polypoid, indurated, necrotic mass is present, 9 cm from the distal margin, involving the subserosal fat. Proximal mucosa has diverticuli and 3 polyps, 0.2 cm, 0.3 cm, and 0.5 cm. A gross assessment is conveyed to O. R., a photograph is taken, and tissue is procured. Representatively submitted:

A1: shave of proximal margin

A2: shave of distal margin

A3-A8: mass

A9: possible diverticuli

A10: polyps

A11: normal appearing mucosa extending into flattened mucosa

A12-A13: proximal, 6 possible lymph nodes in each cassette

A14: proximal, 1 lymph node

A15-A16: distal, 6 possible lymph nodes in each cassette

A17: distal, 4 lymph nodes

DIAGNOSIS:

COLON, LEFT, RESECTION:

- INVASIVE MUCINOUS ADENOCARCINOMA, MODERATELY DIFFERENTIATED, ARISING IN A TUBULOVILLOUS ADENOMA.
- TUMOR MEASURES 9 X 6.5 X 3 CM.
- TUMOR INVOLVES THE SUBSerosa.
- MARGINS, FREE OF TUMOR.
- METASTATIC CARCINOMA IN TWO OF 26 LYMPH NODES (2/26).
- TWO TUBULAR ADENOMAS.
- DIVERTICULOSIS.

NOTE: On slide A3, mucin with fibrosis and marked inflammation is seen at an inked radial aspect that is fragmented. Tumor is not definitely identified at the radial margin. Dr. concurs. Clinical-surgical correlation is recommended.

SYNOPTIC REPORT - COLON & RECTUM

Specimen Type: Left hemicolectomy

Tumor Site: Left (descending) colon

Tumor Configuration: Exophytic (polypoid)

Infiltrative

Tumor size: 9cm Additional dimensions 6.5cm x 3cm

WHO Classification

Mucinous adenocarcinoma 8480/3

Histologic Grade: G2: Moderately differentiated

Extent of Invasion: Subserosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Venous/Lymphatic Invasion: Present

Perineural Invasion: Absent

Additional Pathologic Findings: Adenoma

Extent of Resection: R0: Complete resection with grossly and microscopically negative margins

Lymph Nodes: Positive 2 / 26

Extranodal extension: Absent

[page 2 of 2]
[REDACTED]

Implants: Absent
Pathological Staging (pTNM): pT 3 N 1 M X

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Colon cancer

[REDACTED]

Source: NCI Genomic Data Commons file 9c6f4e25-8225-48fa-be58-6d4ea0e4c8b3 (TCGA-G4-6322.3E8F1C36-63D9-4F6E-8C16-B2E74F8FD138.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).